Somatic mutation profile of tumor specimen TCGA-DJ-A3UR-01A (aliquot TCGA-DJ-A3UR-01A-11D-A22D-08) from TCGA case TCGA-DJ-A3UR, project TCGA-THCA (Thyroid Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Papillary carcinoma, follicular variant; Tissue or organ of origin: Thyroid gland; AJCC pathologic stage: Stage III; Age at diagnosis: 51.5 years (18,808 days).
Specimen TCGA-DJ-A3UR-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 67e74c66-ffe6-4814-a8a4-cc8f60d1cee7.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DJ-A3UR-10A (Blood Derived Normal), aliquot TCGA-DJ-A3UR-10A-01D-A22D-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/26e7cbd0-41a1-4827-8f8d-d47343613b1f

The open-access MAF lists 5 somatic variants for this specimen: 4 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 3, Silent 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 49/115 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- GNAS | c.751G>C p.G251R | Missense Mutation (SNP) | VAF 16/35 reads (46%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.338); catalogued as rs747005037, COSV58333403, COSV58347402; called by muse, mutect2, varscan2
- TNR | c.3098T>A p.I1033N | Missense Mutation (SNP) | VAF 36/230 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.305); catalogued as COSV54917675; called by muse, mutect2, varscan2
- WDFY3 | c.4575dup p.L1526Tfs*7 | Frame Shift Ins (INS) | VAF 31/79 reads (39%) | called by mutect2, pindel, varscan2
- TUBA3D | c.138C>T p.D46= | Silent (SNP) | VAF 59/157 reads (38%) | catalogued as rs758952130, COSV58313603; called by muse, mutect2, varscan2
